Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25P, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25P-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS -----

THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Left lobe

HISTOLOGIC TYPE: Papillary carcinoma involving the thyroid capsule

TUMOR SIZE: Greatest dimension: 0.7 cm

FOCALITY: Multifocal (0.7, 0.1 and 0.1 cm)

LYMPH NODES: All 3 nodes negative for tumor

EXTENT OF INVASION

PRIMARY TUMOR:

pT1: Tumor size <2 cm, limited to thyroid

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS: Margins are uninvolved

VENOUS/LYMPHATIC INVASION: Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Right parathyroid present

ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

hw
5/4/11

[page 2 of 2]
PART #1: TOTAL THYROID

Dictated:

The specimen is received fresh labeled with the patient's name, xxxx and is designated 'total thyroid'. The specimen consists of a grossly recognizable thyroid weighing 39.0 gm. The left lobe measures 5.6 x 3.0 x 2.0 cm and the right lobe measures 6.0 x 3.0 x 1.7 cm. The isthmus measures 4.0 x 1.2 x 0.5 cm. The anterior aspect of the specimen is inked black and the posterior aspect of the specimen is inked orange. A stitch is noted on the specimen marking a thyroid nodule. The specimen is serially sectioned from superior to inferior and grossly there is no nodule associated with the suture. A tan-white and well circumscribed nodule is noted and located in the superior portion of the left lobe measuring 0.6 x 0.5 x 0.4 cm. Upon cut section, the nodule has a tan-white appearance with no hemorrhage or necrosis identified. The uninvolved thyroid has a tan-brown appearance and is grossly unremarkable. The entire specimen is submitted.

SUMMARY OF SECTIONS:

4 - A - D - 2,1,1,1 (LEFT UPPER LOBE)
3 - E - G - 1 EACH (LEFT MIDDLE LOBE)
4 - H - K - 1 EACH (LEFT LOWER LOBE)
3 - L - N - 4,2,2 (ISTHMUS)
2 - O,P - 2 (RIGHT UPPER LOBE)
4 - Q-T - 1 EACH (RIGHT MIDDLE LOBE)
4 - U-X - 1,1,1,2 (RIGHT LOWER LOBE)
24 - TOTAL - M

Source: NCI Genomic Data Commons file 5d15df90-55f9-4f82-865f-a10513f43ba5 (TCGA-ET-A25P.7DB080AA-113F-4F72-8379-6390122762D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).